CCG case CUPP-B7OJ — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c0eb1cdb-a351-4541-b952-ffd96a4c27ae

Demographics
Sex at birth: male; Race: other; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 488 days (1.3 years); Year of death: 2010; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Non-small cell carcinoma: ICD-O-3 morphology code: 8046/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2008; Prior malignancy: no.

Follow-up (1 entry)
- Days to follow up: 488 days (1.3 years); Year of follow up: 2010.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7OJ-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7OJ-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
